Somatic mutation profile of tumor specimen TCGA-CM-6678-01A (aliquot TCGA-CM-6678-01A-11D-1835-10) from TCGA case TCGA-CM-6678, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 63.2 years (23,070 days).
Specimen TCGA-CM-6678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c61891c7-8a34-4a03-8247-43d2991e40b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6678-10A (Blood Derived Normal), aliquot TCGA-CM-6678-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6cddca7-b827-4402-8703-9342cac0d2ab

The open-access MAF lists 151 somatic variants for this specimen: 108 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 40, Nonsense Mutation 10, Frame Shift Ins 4, Splice Site 3, Intron 2, Frame Shift Del 2, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 87/203 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 60/192 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADAMTS19 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs548757432, COSV50731429; called by muse, mutect2, varscan2
- ADGRL4 | c.1220C>A p.T407K | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66060419; called by muse, mutect2, varscan2
- ADGRV1 | c.14962G>A p.A4988T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV67981212; called by muse, mutect2, varscan2
- AK4 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs778627421, COSV59196670; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- AQP8 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54844611; called by muse, mutect2, varscan2
- ASB11 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60354700; called by muse, mutect2, varscan2
- ASPM | c.4474G>A p.V1492I | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.557); catalogued as COSV54127103; called by muse, mutect2, varscan2
- ATP4B | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 133/313 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369809506, COSV58928660; called by muse, mutect2, varscan2
- BAZ1A | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as COSV62409577; called by muse, mutect2, varscan2
- BCL9 | c.1841G>A p.G614D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52342318; called by muse, mutect2, varscan2
- BCO2 | c.955T>C p.F319L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV63062873; called by muse, mutect2, varscan2
- BDP1 | c.2593A>T p.I865F | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62429957; called by muse, mutect2, varscan2
- BRINP3 | c.2015G>A p.S672N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV66517557, COSV66532855; called by muse, mutect2, varscan2
- CAD | c.4237T>C p.Y1413H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99255111; called by mutect2, varscan2
- CADPS2 | c.3239G>T p.C1080F | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100463079; called by muse, mutect2
- CATSPER1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1033780625, COSV100375988, COSV56412522; called by muse, mutect2, varscan2
- CCDC3 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs754059035, COSV66558962; called by muse, mutect2, varscan2
- CCKBR | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1450663271, COSV58099794; called by muse, mutect2, varscan2
- CHM | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs1357495676, CM137294, COSV62564733; called by muse, mutect2, varscan2
- CILP2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1472767769, COSV52273486; called by muse, mutect2, varscan2
- CNOT1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57764018; called by muse, mutect2, varscan2
- CNOT4 | c.1902G>A p.W634* (on ENST00000541284 / NM_001190850.1; = p.W560* on NM_013316.4) | Nonsense Mutation (SNP) | VAF 46/96 reads (48%) | catalogued as COSV64156985, COSV64157920; called by muse, mutect2, varscan2
- CNTNAP5 | c.3118A>T p.I1040F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV70473052; called by muse, mutect2
- CREB5 | c.812A>G p.H271R (on ENST00000357727 / NM_182898.4; = p.H264R on NM_004904.3) | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.95); catalogued as COSV63218652; called by muse, mutect2, varscan2
- DIP2A | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV59474718; called by muse, mutect2, varscan2
- DMRT3 | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs770644071, COSV99505886; called by muse, mutect2, varscan2
- DNER | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs143332732; called by muse, mutect2, varscan2
- DYNC1I1 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61456083, COSV61470906; called by muse, mutect2, varscan2
- FAM47B | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 84/235 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV61452375, COSV61453008; called by muse, mutect2, varscan2
- FAM78B | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.04); catalogued as rs144142558, COSV57976033; called by muse, mutect2, varscan2
- FBN3 | c.3314C>T p.T1105M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs145578557; called by muse, mutect2, varscan2
- FKBP9 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs761363029, COSV54228963; called by muse, mutect2, varscan2
- FNDC1 | c.1573C>A p.L525I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.162); catalogued as COSV51933758; called by muse, mutect2, varscan2
- FNDC1 | c.5171C>T p.T1724M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs981479986, COSV51933770; called by muse, mutect2, varscan2
- G6PD | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV54838294; called by muse, mutect2, varscan2
- GLT1D1 | c.730G>A p.A244T (on ENST00000442111 / NM_001366889.1; = p.A164T on NM_144669.3) | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs759619312, COSV55878029; called by muse, mutect2, varscan2
- GPC1 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs750226747, COSV50862940; called by muse, mutect2, varscan2
- HAS1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55786767, COSV55786789; called by muse, mutect2, varscan2
- HFM1 | c.3140+1G>A p.X1047_splice | Splice Site (SNP) | VAF 32/109 reads (29%) | catalogued as rs762180649, COSV54020824, COSV54023132; called by muse, mutect2, varscan2
- HSPA1L | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.698); catalogued as rs142416335; called by muse, mutect2, varscan2
- IGHV3-30 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 26/216 reads (12%) | catalogued as rs1170624423; called by muse, mutect2, varscan2
- KCNA5 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52904601, COSV99363733; called by muse, mutect2, varscan2
- KCNG1 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV65368564; called by muse, mutect2, varscan2
- KRT31 | c.130T>G p.C44G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV52434105; called by muse, mutect2, varscan2
- MAST1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766694390, COSV52243329; called by muse, mutect2, varscan2
- MED12 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 35/210 reads (17%) | catalogued as COSV61335406; called by muse, mutect2, varscan2
- MINDY4 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54672576; called by muse, mutect2, varscan2
- MME | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs200966070, COSV64706524; called by muse, mutect2, varscan2
- MSRB3 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568898551, COSV57587847, COSV57598706; called by muse, mutect2, varscan2
- NACC1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52834197, COSV99456973; called by muse, mutect2, varscan2
- NCBP2L | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64943879; called by muse, mutect2, varscan2
- NFE2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV56455186; called by muse, mutect2
- NOL6 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs764376131, COSV53040282; called by muse, mutect2, varscan2
- NPHS1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.508); catalogued as rs770750372, COSV62287019, COSV62287754; called by muse, mutect2, varscan2
- NR2E1 | c.989A>C p.H330P | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV64561713; called by muse, mutect2, varscan2
- OLFM1 | c.1441C>T p.R481C (on ENST00000371793 / NM_001282611.2; = p.R463C on NM_014279.5) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1401300491, COSV53277207; called by muse, mutect2, varscan2
- OR10J5 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58385563, COSV58386029; called by muse, mutect2, varscan2
- OR4Q3 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV59177878, COSV59181049; called by muse, mutect2, varscan2
- P3H3 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99301263; called by muse, mutect2, varscan2
- PCDHB8 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 26/658 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99176985; called by muse, mutect2
- PCDHGA9 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.298); catalogued as COSV53917968; called by muse, mutect2, varscan2
- PIGA | c.78del p.Y26* | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | catalogued as COSV61237257; called by mutect2, pindel*, varscan2
- POLE | c.1882G>A p.G628R | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57677011; called by muse, mutect2, varscan2
- PRKG1 | c.896T>C p.L299S | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV64768048; called by muse, mutect2, varscan2
- PRKN | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58210344, COSV58228491; called by muse, mutect2, varscan2
- PTPRZ1 | c.2372A>T p.D791V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV66433296; called by muse, mutect2, varscan2
- RBM15B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1379123704, COSV60371475; called by muse, mutect2, varscan2
- RIC3 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV58301163, COSV58302612; called by muse, mutect2, varscan2
- SALL4 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV53850963; called by muse, mutect2, varscan2
- SCN3A | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376645098, COSV51805409; called by muse, mutect2, varscan2
- SENP7 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58609880; called by muse, mutect2, varscan2
- SLC10A3 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371811548, COSV54835910; called by muse, mutect2, varscan2
- SLC25A5 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 105/286 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV58625721; called by muse, mutect2, varscan2
- SPATA31D1 | c.2903C>G p.T968S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.06); catalogued as COSV61194013; called by muse, mutect2, varscan2
- SULT4A1 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50780533, COSV99970633; called by muse, mutect2, varscan2
- SYP | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 14/345 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs372570311; called by muse, mutect2
- TESK2 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100517392; called by muse, mutect2, varscan2
- TET1 | c.6326C>T p.A2109V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65383257; called by muse, mutect2, varscan2
- TMEM132B | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 35/148 reads (24%) | catalogued as COSV54748622, COSV54765265; called by muse, mutect2, varscan2
- TRAPPC12 | c.1882T>C p.F628L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.615); catalogued as COSV100160565; called by muse, varscan2
- TRHDE | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as rs200482271, COSV53857265; called by muse, mutect2, varscan2
- TSHZ1 | c.2678A>G p.N893S (on ENST00000580243 / NM_001308210.2; = p.N848S on NM_005786.6) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100433722; called by muse, mutect2, varscan2
- TTC14 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs149196386; called by muse, mutect2, varscan2
- TUBA3C | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.24); catalogued as rs768296332, COSV68027880; called by muse, mutect2, varscan2
- UCN2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781323282, COSV56476229; called by muse, mutect2, varscan2
- ZCWPW2 | c.167A>C p.E56A | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV67498113; called by muse, mutect2, varscan2
- ZHX1 | c.2323C>T p.L775F | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as COSV52875892; called by muse, mutect2, varscan2
- ZNF154 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70744870; called by muse, mutect2, varscan2
- ZNF208 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.499); catalogued as COSV68102724, COSV68105097; called by muse, mutect2
- ZNF578 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV69736212; called by muse, mutect2, varscan2
- APC | c.4306_4307dup p.S1436Rfs*38 | Frame Shift Ins (INS) | VAF 46/129 reads (36%) | called by mutect2, pindel, varscan2
- ARAF | c.1092_1098dup p.L367Qfs*22 | Frame Shift Ins (INS) | VAF 46/158 reads (29%) | called by mutect2, varscan2
- ARHGAP5 | c.170_172dup p.L57_S58insI | In Frame Ins (INS) | VAF 24/132 reads (18%) | called by pindel, varscan2
- BDP1 | c.7743+2T>C p.X2581_splice | Splice Site (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- C1orf87 | c.1421G>A p.W474* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- CSMD3 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2
- KIR2DL1 | c.1041C>A p.C347* | Nonsense Mutation (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- LHX1 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LPGAT1 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- MYLIP | c.662+2T>C p.X221_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- PDZD8 | c.2906_2907del p.K969Tfs*12 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- SYNE1 | c.6998dup p.N2333Kfs*2 (on ENST00000367255 / NM_182961.4; = p.N2340Kfs*2 on NM_033071.3) | Frame Shift Ins (INS) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- TNFAIP8L3 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); called by muse, mutect2
- TSHZ1 | c.431G>A p.S144N (on ENST00000580243 / NM_001308210.2; = p.S99N on NM_005786.6) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, varscan2
- ZNF12 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 19/88 reads (22%) | called by mutect2, pindel, varscan2
- ARSI | c.516G>A p.T172= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs745556136, COSV60816998; called by muse, mutect2, varscan2
- ATP2B4 | c.2283G>A p.K761= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV58175664; called by muse, mutect2, varscan2
- ATP8B4 | c.1506C>T p.A502= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs377569154; called by muse, mutect2, varscan2
- CDC42BPA | c.2616G>A p.A872= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs200154961, COSV62006045; called by muse, mutect2, varscan2
- CDX4 | c.45G>A p.P15= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs367670478, COSV65171529; called by muse, mutect2, varscan2
- CLNK | c.1254A>C p.P418= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV99905253; called by muse, mutect2, varscan2
- CNP | c.246G>A p.S82= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs782433665, COSV66367755; called by muse, mutect2, varscan2
- CRISP3 | c.696A>G p.G232= (on ENST00000371159 / NM_001368123.1; = p.G214= on NM_006061.4) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99538968; called by muse, mutect2, varscan2
- CYLD | c.675C>T p.V225= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs184354524, COSV61093625; called by muse, mutect2, varscan2
- DMRTB1 | c.132C>T p.S44= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1474180643, COSV65112821; called by muse, mutect2, varscan2
- DNAH1 | c.5055G>A p.P1685= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs761433531, COSV70229274; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAH7 | c.4968C>T p.Y1656= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as rs201006443, COSV56757174; called by muse, mutect2, varscan2
- DRP2 | c.1857G>A p.K619= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV65809824; called by muse, mutect2, varscan2
- DYRK1B | c.666C>T p.C222= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100546612; called by muse, mutect2, varscan2
- ENKUR | c.114C>T p.D38= | Silent (SNP) | VAF 48/261 reads (18%) | catalogued as COSV58632726, COSV58633949; called by muse, mutect2, varscan2
- EXPH5 | c.5416C>T p.L1806= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV56198399, COSV56206075; called by muse, mutect2, varscan2
- JAG2 | c.2268G>T p.L756= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV59307608; called by muse, mutect2, varscan2
- KCNT1 | c.1926C>T p.P642= (on ENST00000488444; = p.P661= on NM_020822.3) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs533528985, COSV53698384; ClinVar: likely benign; called by muse, mutect2, varscan2
- LHFPL3 | c.111C>T p.N37= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV67804741; called by muse, mutect2, varscan2
- MAS1 | c.654G>A p.T218= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs758145350, COSV53120837; called by muse, mutect2, varscan2
- MYH3 | c.2727G>T p.L909= | Silent (SNP) | VAF 60/136 reads (44%) | catalogued as rs1171236402, COSV56862776; called by muse, varscan2
- NSD2 | c.1653G>C p.T551= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100373371; called by muse, mutect2, varscan2
- OR9A4 | c.654C>T p.N218= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs782497009, COSV71885195; called by muse, mutect2, varscan2
- PCDHA11 | c.795C>T p.N265= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs782158709, COSV56486648; called by muse, mutect2, varscan2
- PCDHA12 | c.1389C>T p.F463= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as COSV56477300; called by muse, mutect2, varscan2
- PCDHA4 | c.1929G>A p.P643= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV63538636; called by muse, mutect2, varscan2
- PCDHB10 | c.1692G>A p.P564= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV53376910; called by mutect2, varscan2
- PCDHB4 | c.153G>T p.L51= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV52020836; called by muse, mutect2, varscan2
- PLPP5 | c.522C>T p.F174= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- PREX2 | c.1695G>A p.S565= | Silent (SNP) | VAF 28/38 reads (74%) | catalogued as rs1386409533, COSV55752115; called by muse, mutect2, varscan2
- SCIMP | c.228G>A p.S76= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs974761908, COSV68310831; called by muse, mutect2, varscan2
- SHROOM2 | c.2559C>T p.N853= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs767943035, COSV66605418; called by muse, mutect2, varscan2
- SIX5 | c.1782C>T p.S594= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs376907921; called by muse, varscan2
- SPAG17 | c.5565G>A p.T1855= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs150806134; called by muse, mutect2, varscan2
- SPHKAP | c.2571C>T p.S857= | Silent (SNP) | VAF 109/194 reads (56%) | catalogued as rs533054194, COSV60872663; called by muse, mutect2, varscan2
- SSX3 | c.369G>A p.S123= | Silent (SNP) | VAF 49/418 reads (12%) | catalogued as rs782073249, COSV53643500; called by muse, mutect2, varscan2
- SYNE4 | c.105C>T p.P35= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as rs200751555; called by muse, mutect2, varscan2
- THSD7A | c.636C>T p.S212= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs760448242, COSV70262366; called by muse, mutect2, varscan2
- XK | c.90G>A p.S30= | Silent (SNP) | VAF 55/177 reads (31%) | catalogued as COSV66119864; called by muse, mutect2, varscan2
- ZNF536 | c.2145G>T p.P715= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1245802145, COSV100835268, COSV62826176; called by muse, mutect2
- FGGY | c.1221+2930C>T | Intron (SNP) | VAF 23/83 reads (28%) | catalogued as rs747128652, COSV58028783; called by muse, mutect2, varscan2
- NXT2 | c.-59G>A | 5'UTR (SNP) | VAF 51/115 reads (44%) | catalogued as COSV54296406; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+671C>T | Intron (SNP) | VAF 46/89 reads (52%) | catalogued as COSV53336375, COSV53339511; called by muse, mutect2, varscan2
